Somatic mutation profile of tumor specimen TCGA-EE-A3JH-06A (aliquot TCGA-EE-A3JH-06A-11D-A21A-08) from TCGA case TCGA-EE-A3JH, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 61.7 years (22,524 days).
Specimen TCGA-EE-A3JH-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4fc4b881-f82a-4c79-b9ae-91116905a099.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A3JH-10A (Blood Derived Normal), aliquot TCGA-EE-A3JH-10A-01D-A21A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2791eebc-0427-47a1-9e21-6cb01bc191f5

The open-access MAF lists 207 somatic variants for this specimen: 128 protein-altering or splice-affecting, 75 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 116, Silent 75, Nonsense Mutation 7, Intron 2, Splice Region 2, RNA 2, Splice Site 1, Translation Start Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1921A>G p.K641E (on ENST00000288602 / NM_001374244.1; = p.K601E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as rs121913364, CM092083, COSV56058494; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MAP2K1 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 31/139 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as rs1057519733, CM083720, COSV61068654; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AC136428.1 | c.241G>A p.D81N | Missense Mutation (SNP) | VAF 30/436 reads (7%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.207); catalogued as COSV101434958; called by muse, mutect2
- ACER2 | c.758G>A p.W253* | Nonsense Mutation (SNP) | VAF 13/101 reads (13%) | catalogued as COSV100575780; called by muse, mutect2, varscan2
- ACER2 | c.759G>A p.W253* | Nonsense Mutation (SNP) | VAF 13/100 reads (13%) | catalogued as COSV100575781; called by muse, mutect2, varscan2
- ADAL | c.706C>T p.L236F | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV67501244; called by muse, mutect2, varscan2
- ADAMDEC1 | c.1375G>A p.D459N | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.296); catalogued as COSV56477126; called by muse, mutect2, varscan2
- ADAMTS12 | c.283A>G p.I95V | Missense Mutation (SNP) | VAF 40/174 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.241); catalogued as COSV61275439; called by muse, mutect2, varscan2
- ADAMTS2 | c.2945G>A p.G982E | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as rs372498555; called by muse, mutect2, varscan2
- AHCTF1 | c.2965C>T p.L989F (on ENST00000366508; = p.L963F on NM_015446.5) | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58254121; called by muse, mutect2
- AK7 | c.1183C>T p.H395Y | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.371); catalogued as COSV50876746; called by muse, mutect2
- AKNA | c.1099C>G p.R367G | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs906817866, COSV56313829, COSV56314478; called by muse, mutect2, varscan2
- AL592490.1 | c.1273G>A p.E425K | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0.095); catalogued as COSV69427538; called by muse, mutect2, varscan2
- ANKRD11 | c.6322G>A p.G2108S | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV56369494; called by muse, varscan2
- ASIC3 | c.352G>A p.D118N | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT tolerated (0.59); PolyPhen benign (0.048); catalogued as COSV52509332; called by muse, mutect2, varscan2
- ASMTL | c.1697C>T p.A566V | Missense Mutation (SNP) | VAF 21/172 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.063); catalogued as rs191726330, COSV67245032; called by muse, mutect2, varscan2
- ATP8B2 | c.2747C>T p.T916I (on ENST00000672630; = p.T883I on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/367 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV59248283; called by muse, mutect2
- ATR | c.7690G>A p.E2564K | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63390844; called by muse, mutect2
- C12orf50 | c.149A>T p.K50I | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV53898142; called by muse, mutect2, varscan2
- CCDC138 | c.1375G>A p.G459R | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99718932; called by muse, mutect2, varscan2
- CCDC138 | c.1376G>A p.G459E | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99718935, COSV99719620; called by muse, mutect2
- CD177 | c.389C>T p.S130F | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs868371538, COSV65122460; called by muse, mutect2
- CDH18 | c.1684G>A p.D562N | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.01); catalogued as rs1207140699, COSV56914692, COSV56923003; called by muse, mutect2, varscan2
- CEMIP2 | c.3628T>G p.Y1210D | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV65486299, COSV65488955; called by muse, mutect2, varscan2
- CHAMP1 | c.1066C>T p.P356S | Missense Mutation (SNP) | VAF 9/152 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.391); catalogued as COSV100778752; called by muse, mutect2
- CHAMP1 | c.1067C>T p.P356L | Missense Mutation (SNP) | VAF 8/155 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as COSV100778753; called by muse, mutect2
- CHMP7 | c.527C>T p.P176L | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.276); catalogued as COSV57533754; called by muse, mutect2, varscan2
- CHST1 | c.89C>T p.S30F | Missense Mutation (SNP) | VAF 17/196 reads (9%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV57325245; called by muse, mutect2
- CNBD1 | c.1179G>A p.M393I | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.581); catalogued as COSV73073831; called by muse, varscan2
- COL4A5 | c.4141C>T p.P1381S | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0.113); catalogued as COSV100087106; called by muse, mutect2, varscan2
- CPXM2 | c.1582G>A p.D528N | Missense Mutation (SNP) | VAF 46/233 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.274); catalogued as rs1217291885, COSV53867392; called by muse, mutect2, varscan2
- CRYBB1 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1400757152, COSV53232441; called by muse, mutect2, varscan2
- CSMD2 | c.3430G>A p.E1144K | Missense Mutation (SNP) | VAF 21/149 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.166); catalogued as rs771073052, COSV53888042; called by muse, mutect2, varscan2
- CTSC | c.743C>T p.P248L | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV57059758; called by muse, mutect2
- CUX1 | c.2774C>T p.P925L | Missense Mutation (SNP) | VAF 40/286 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs948149624, COSV52912005; called by muse, mutect2, varscan2
- DACT1 | c.1061G>A p.R354K | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100241697; called by mutect2, varscan2
- DDI1 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs748236770, COSV56390999; called by muse, mutect2
- DDX60L | c.1240C>T p.P414S | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as COSV52720259; called by muse, mutect2, varscan2
- DZIP1 | c.2411G>A p.G804E (on ENST00000347108; = p.G785E on NM_014934.5) | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.52); PolyPhen benign (0.03); catalogued as rs1016281699, COSV61265333; called by muse, mutect2, varscan2
- EDAR | c.394G>A p.G132S | Missense Mutation (SNP) | VAF 22/290 reads (8%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.784); catalogued as COSV51506924; called by muse, mutect2
- EHBP1L1 | c.611C>T p.A204V | Missense Mutation (SNP) | VAF 7/110 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.01); catalogued as COSV58574638; called by muse, mutect2
- EHMT2 | c.1645C>T p.P549S | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV64997725; called by muse, mutect2, varscan2
- EIF2D | c.1091C>T p.S364F | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.071); catalogued as COSV55115178; called by muse, mutect2, varscan2
- ELP2 | c.1881G>C p.K627N | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV60853831; called by muse, mutect2
- ERMAP | c.413C>T p.T138I | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.714); catalogued as COSV60275610; called by muse, mutect2, varscan2
- F7 | c.872C>G p.P291R | Missense Mutation (SNP) | VAF 14/206 reads (7%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.98); catalogued as COSV60647629; called by muse, mutect2
- GALNT13 | c.1060C>T p.P354S | Missense Mutation (SNP) | VAF 17/154 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.15); catalogued as COSV67215769; called by muse, mutect2, varscan2
- GALNT15 | c.407G>A p.G136E | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.037); catalogued as rs1212316385, COSV100327427; called by muse, mutect2, varscan2
- GFM1 | c.1384G>A p.D462N | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.187); catalogued as rs200244667, COSV51835191; called by muse, mutect2, varscan2
- GPC1 | c.1321G>A p.E441K | Missense Mutation (SNP) | VAF 18/150 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1206538075, COSV50863014; called by muse, mutect2, varscan2
- GPHN | c.466C>T p.Q156* | Nonsense Mutation (SNP) | VAF 10/103 reads (10%) | catalogued as COSV59490737; called by muse, mutect2
- GPN2 | c.424C>T p.H142Y | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.145); catalogued as COSV64652588; called by muse, mutect2, varscan2
- GPR176 | c.1462C>T p.Q488* | Nonsense Mutation (SNP) | VAF 29/147 reads (20%) | catalogued as rs147730816, COSV54445259, COSV54447822; called by muse, mutect2, varscan2
- HECTD1 | c.853A>T p.T285S | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.114); catalogued as COSV67948774; called by muse, mutect2, varscan2
- IGHG1 | c.775G>A p.D259N | Missense Mutation (SNP) | VAF 78/306 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.902); catalogued as rs778627526; called by muse, mutect2, varscan2
- IGSF9 | c.143G>A p.G48D | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); catalogued as rs1360863130, COSV100829648, COSV63641853; called by muse, mutect2, varscan2
- IMPDH1 | c.203C>T p.S68F (on ENST00000470772 / NM_001142573.2; = p.S153F on NM_000883.4) | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as COSV58317711; called by muse, mutect2, varscan2
- KCNB1 | c.2485G>A p.E829K | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.255); catalogued as COSV65568996, COSV65570260; called by muse, mutect2, varscan2
- KRT16 | c.38C>T p.S13F | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.823); catalogued as COSV56969378; called by muse, mutect2
- LINGO2 | c.1763G>A p.G588D | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1003199962, COSV58063298; called by muse, mutect2, varscan2
- MAGEB6B | c.359C>T p.S120L | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV69689602; called by muse, mutect2, varscan2
- MAGI1 | c.3722C>T p.S1241L | Missense Mutation (SNP) | VAF 35/212 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.083); catalogued as rs139105394; called by muse, mutect2, varscan2
- MBD5 | c.1306C>T p.P436S | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV68698712; called by muse, mutect2
- MUC2 | c.404C>T p.P135L | Missense Mutation (SNP) | VAF 40/420 reads (10%) | SIFT tolerated, low confidence (0.2); catalogued as rs199731067; called by muse, mutect2
- MYH6 | c.2558C>T p.T853I | Missense Mutation (SNP) | VAF 31/162 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.036); catalogued as COSV62453824; called by muse, mutect2, varscan2
- NAGK | c.733C>T p.H245Y | Missense Mutation (SNP) | VAF 9/118 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.192); catalogued as COSV54904349; called by muse, mutect2
- NCF1 | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1254491876, COSV56877186, COSV99194294; called by muse, mutect2, varscan2
- NCKAP5 | c.4399C>T p.P1467S | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.164); catalogued as COSV58469074; called by muse, mutect2, varscan2
- NLRP9 | c.1501G>A p.E501K | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.215); catalogued as COSV60466951; called by muse, mutect2, varscan2
- NLRX1 | c.770G>C p.G257A | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.009); catalogued as COSV52708559; called by muse, mutect2, varscan2
- NR6A1 | c.361C>T p.L121F (on ENST00000487099 / NM_033334.4; = p.L117F on NM_001489.5) | Missense Mutation (SNP) | VAF 36/190 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1393089900, COSV60636878; called by muse, mutect2, varscan2
- NXN | c.497G>A p.G166E | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.997); catalogued as COSV100402867; called by muse, mutect2
- NXN | c.496G>A p.G166R | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.69); PolyPhen probably damaging (0.998); catalogued as COSV100402868; called by muse, mutect2
- OR11H6 | c.739C>T p.P247S | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.859); catalogued as COSV59644287; called by muse, mutect2, varscan2
- OR13C5 | c.166C>T p.H56Y | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV101053037; called by muse, varscan2
- OR2A2 | c.358G>A p.D120N | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763818273, COSV68872280, COSV68872394; called by muse, mutect2, varscan2
- OR2T11 | c.151C>T p.R51C | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs768659249, COSV58185932; called by muse, mutect2, varscan2
- OR3A3 | c.596C>T p.S199F | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752038909, COSV52167252, COSV52168343; called by muse, mutect2, varscan2
- OR4B1 | c.890G>A p.R297K | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.69); PolyPhen benign (0.01); catalogued as COSV58883744; called by muse, mutect2, varscan2
- OSBPL5 | c.1699C>T p.Q567* | Nonsense Mutation (SNP) | VAF 9/63 reads (14%) | catalogued as COSV55144952; called by muse, mutect2, varscan2
- PATJ | c.2390C>T p.S797L | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs1404651157, COSV57160564; called by muse, mutect2, varscan2
- PCDHB6 | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT tolerated (0.71); PolyPhen benign (0.01); catalogued as rs782536394, COSV50690800; called by muse, mutect2
- PDZD2 | c.1058G>A p.G353E | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56870028; called by muse, mutect2, varscan2
- PEDS1-UBE2V1 | c.966G>A p.V322= | Splice Region (SNP) | VAF 7/55 reads (13%) | catalogued as COSV59015325; called by muse, mutect2, varscan2
- PLA2G4E | c.1631G>A p.G544E | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68151976; called by muse, mutect2, varscan2
- PLA2G5 | c.185+1G>A p.X62_splice | Splice Site (SNP) | VAF 13/113 reads (12%) | catalogued as COSV64283286; called by muse, mutect2, varscan2
- POM121L12 | c.360G>A p.M120I | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.141); catalogued as COSV68693043; called by muse, mutect2, varscan2
- PPIP5K1 | c.794C>T p.P265L | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV100613144; called by mutect2, varscan2
- PPIP5K1 | c.793C>T p.P265S | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.352); catalogued as COSV100613147; called by mutect2, varscan2
- PRPF6 | c.1786C>T p.L596F | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.671); catalogued as COSV53877190; called by muse, mutect2, varscan2
- PRSS16 | c.1169C>T p.P390L | Missense Mutation (SNP) | VAF 28/275 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as COSV57916606; called by muse, mutect2
- PTGS2 | c.89G>A p.G30D | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV66571327; called by muse, mutect2, varscan2
- RAB11FIP3 | c.1441G>A p.A481T | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.52); PolyPhen benign (0.115); catalogued as rs779911476, COSV51936985; called by muse, mutect2, varscan2
- RIPOR2 | c.1547C>T p.S516F | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.655); catalogued as COSV52427779; called by muse, mutect2, varscan2
- RYR3 | c.8957C>T p.S2986F (on ENST00000389232; = p.S2987F on NM_001036.6) | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV66805369; called by muse, mutect2, varscan2
- SBK1 | c.142G>A p.D48N | Missense Mutation (SNP) | VAF 34/161 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.51); catalogued as rs866142747, COSV59398606; called by muse, mutect2, varscan2
- SCN2A | c.3037G>A p.G1013R | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs780508905, CM124405, COSV51850744; called by muse, mutect2, varscan2
- SCN5A | c.4073G>A p.G1358E (on ENST00000333535 / NM_198056.3; = p.G1357E on NM_000335.5) | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61138162; called by muse, mutect2, varscan2
- SDC3 | c.1096G>T p.D366Y | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59580359; called by muse, mutect2, varscan2
- SFRP4 | c.640G>A p.V214I | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated (0.59); PolyPhen benign (0.065); catalogued as COSV101460877; called by muse, mutect2
- SH2B1 | c.487C>T p.R163* | Nonsense Mutation (SNP) | VAF 24/151 reads (16%) | catalogued as COSV59465173; called by muse, mutect2, varscan2
- SLC34A3 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 36/376 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.143); catalogued as rs759132724, COSV63187853; called by muse, mutect2
- SRRT | c.942G>A p.Q314= | Splice Region (SNP) | VAF 6/56 reads (11%) | catalogued as COSV61454285; called by muse, mutect2
- TBX2 | c.1850C>T p.P617L | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV53600816; called by muse, mutect2, varscan2
- TCTE1 | c.784C>T p.L262F | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.687); catalogued as rs936553043, COSV65256243; called by muse, mutect2
- TMCC1 | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.176); catalogued as COSV67874472; called by muse, mutect2, varscan2
- TMEM131 | c.4700T>A p.V1567D | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV51784196; called by muse, mutect2, varscan2
- TMIGD1 | c.572G>A p.G191E | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61029224; called by muse, mutect2
- TRAT1 | c.470C>T p.S157F | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.568); catalogued as COSV55467551, COSV55467662; called by muse, mutect2, varscan2
- TRIO | c.7543C>T p.R2515C | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV59990054, COSV59992182; called by muse, varscan2
- UBA7 | c.403G>A p.V135M | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.213); catalogued as COSV61093334; called by muse, mutect2, varscan2
- UNC119 | c.592C>T p.P198S | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0.012); catalogued as COSV99971641; called by muse, mutect2, varscan2
- USP29 | c.458C>T p.S153L | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0.063); catalogued as COSV54139700; called by muse, mutect2, varscan2
- USP6 | c.2044C>T p.H682Y | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated, low confidence (0.2); PolyPhen probably damaging (0.984); catalogued as COSV100003516; called by muse, mutect2, varscan2
- VEZT | c.424C>T p.P142S | Missense Mutation (SNP) | VAF 16/262 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.476); catalogued as COSV54144059; called by muse, mutect2
- WDFY3 | c.6487G>A p.E2163K | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.027); catalogued as COSV55695163, COSV99882710; called by muse, mutect2, varscan2
- WFDC12 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65661316; called by muse, mutect2, varscan2
- WTAP | c.913T>C p.S305P | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs755139888, COSV64330628; called by muse, mutect2, varscan2
- XDH | c.1975G>A p.D659N | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.175); catalogued as COSV65150813; called by muse, mutect2, varscan2
- YTHDF1 | c.200C>T p.P67L | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.49); catalogued as COSV64833799; called by muse, mutect2, varscan2
- ZC4H2 | c.558G>A p.M186I | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV62005753; called by muse, mutect2, varscan2
- ZKSCAN5 | c.1643C>T p.P548L | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58744268; called by muse, mutect2, varscan2
- ZNF366 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.005); catalogued as rs764343933, COSV59214152; called by muse, mutect2
- DDX5 | c.1273dup p.Y425Lfs*24 | Frame Shift Ins (INS) | VAF 14/127 reads (11%) | called by mutect2, pindel, varscan2
- FCGBP | c.6766C>T p.Q2256* | Nonsense Mutation (SNP) | VAF 12/272 reads (4%) | called by muse, mutect2
- GRM8 | c.1277G>A p.G426E | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.942); called by mutect2, varscan2
- IGHV3-23 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 15/213 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.308); called by muse, mutect2
- MAGEB6B | c.716G>A p.R239K | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ASIC2 | c.462G>A p.L154= | Silent (SNP) | VAF 35/190 reads (18%) | catalogued as COSV63325247; called by muse, mutect2, varscan2
- CELF5 | c.879C>T p.I293= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as rs144542912; called by muse, mutect2, varscan2
- CLCA1 | c.2196C>T p.S732= | Silent (SNP) | VAF 12/162 reads (7%) | catalogued as COSV52330513; called by muse, mutect2
- CLTCL1 | c.2223C>T p.I741= | Silent (SNP) | VAF 12/73 reads (16%) | catalogued as rs1158754703, COSV54237660, COSV99595494; called by muse, mutect2, varscan2
- COL19A1 | c.355C>T p.L119= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV59584509; called by mutect2, varscan2
- COL4A5 | c.4140C>T p.I1380= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV100090744, COSV60372506; called by muse, mutect2, varscan2
- CTNND2 | c.3549C>T p.S1183= | Silent (SNP) | VAF 29/157 reads (18%) | catalogued as rs1288565690, COSV58891556, COSV58899350; called by muse, mutect2, varscan2
- DACT1 | c.1062G>A p.R354= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV100241701, COSV60020208; called by mutect2, varscan2
- DCC | c.292C>T p.L98= | Silent (SNP) | VAF 8/79 reads (10%) | catalogued as COSV59128360; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.2100C>T p.F700= | Silent (SNP) | VAF 24/212 reads (11%) | catalogued as COSV62570290; called by muse, mutect2, varscan2
- FAM135B | c.3519C>T p.F1173= | Silent (SNP) | VAF 10/63 reads (16%) | catalogued as COSV52724035; called by muse, mutect2, varscan2
- FCGR3A | c.325C>T p.L109= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as COSV63460422; called by muse, mutect2, varscan2
- FER1L5 | c.5052G>A p.K1684= (on ENST00000623019; = p.K1657= on NM_001293083.2) | Silent (SNP) | VAF 13/85 reads (15%) | catalogued as COSV67606827; called by muse, mutect2, varscan2
- FOLH1 | c.1746G>A p.G582= | Silent (SNP) | VAF 5/51 reads (10%) | called by muse, mutect2, varscan2
- GALNT15 | c.408G>A p.G136= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as COSV100327429, COSV60220472; called by muse, mutect2, varscan2
- GIMAP8 | c.1671G>A p.T557= | Silent (SNP) | VAF 36/157 reads (23%) | catalogued as rs557029400, COSV56230717; called by muse, mutect2, varscan2
- HECTD4 | c.5142C>T p.L1714= | Silent (SNP) | VAF 39/254 reads (15%) | catalogued as COSV66393151; called by muse, mutect2, varscan2
- HSD17B7 | c.543C>T p.L181= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as rs370344067, COSV99597610; called by muse, mutect2, varscan2
- IGDCC3 | c.2163C>T p.F721= | Silent (SNP) | VAF 55/345 reads (16%) | catalogued as COSV60076867, COSV60077699, COSV60079011; called by muse, mutect2, varscan2
- IGHM | c.180G>A p.L60= | Silent (SNP) | VAF 9/48 reads (19%) | called by muse, mutect2, varscan2
- IGHV2-70 | c.270C>T p.I90= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as rs369407281; called by muse, mutect2, varscan2
- IGSF9 | c.2044C>T p.L682= (on ENST00000368094 / NM_001135050.2; = p.L666= on NM_020789.4) | Silent (SNP) | VAF 27/179 reads (15%) | catalogued as COSV63641842; called by muse, mutect2, varscan2
- KAT6B | c.2151C>T p.G717= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as COSV54753226; called by muse, mutect2, varscan2
- KIF15 | c.1863G>A p.Q621= | Silent (SNP) | VAF 9/112 reads (8%) | catalogued as COSV58164188; called by muse, mutect2
- KRT74 | c.1125G>A p.V375= | Silent (SNP) | VAF 9/156 reads (6%) | catalogued as COSV59773345; called by muse, mutect2
- LRP1 | c.6237C>T p.I2079= | Silent (SNP) | VAF 9/79 reads (11%) | catalogued as rs200892627, COSV54522893; called by muse, mutect2
- ME2 | c.1692C>T p.S564= | Silent (SNP) | VAF 32/112 reads (29%) | catalogued as rs751407952, COSV58424666; called by muse, mutect2, varscan2
- MOSPD3 | c.681C>T p.L227= | Silent (SNP) | VAF 18/160 reads (11%) | catalogued as rs371056560; called by muse, mutect2, varscan2
- MST1 | c.1731G>A p.G577= | Silent (SNP) | VAF 12/91 reads (13%) | catalogued as COSV56536266; called by muse, mutect2, varscan2
- NOS2 | c.249G>A p.R83= | Silent (SNP) | VAF 23/326 reads (7%) | catalogued as rs199582562, COSV58226789; called by muse, mutect2
- OAS2 | c.1905C>T p.I635= | Silent (SNP) | VAF 34/227 reads (15%) | catalogued as COSV60804143; called by muse, mutect2, varscan2
- OR2B3 | c.306C>T p.I102= | Silent (SNP) | VAF 18/131 reads (14%) | catalogued as COSV65851154; called by muse, mutect2, varscan2
- OR2G3 | c.837C>T p.T279= | Silent (SNP) | VAF 4/62 reads (6%) | catalogued as COSV60682846; called by muse, mutect2
- OR2K2 | c.345G>C p.L115= (on ENST00000374428; = p.L86= on NM_205859.2) | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV57018286; called by muse, mutect2, varscan2
- OR2M4 | c.39C>T p.I13= | Silent (SNP) | VAF 14/108 reads (13%) | catalogued as rs1384491211, COSV60709414; called by muse, mutect2, varscan2
- OSBP2 | c.1026C>T p.I342= | Silent (SNP) | VAF 8/63 reads (13%) | catalogued as COSV60247612; called by muse, mutect2, varscan2
- PCDHB16 | c.1074G>A p.E358= | Silent (SNP) | VAF 10/128 reads (8%) | catalogued as rs782085676, COSV53357553, COSV53369339; called by muse, mutect2
- PCDHB3 | c.522G>A p.P174= | Silent (SNP) | VAF 12/150 reads (8%) | catalogued as COSV50565788; called by muse, mutect2
- PCDHGA10 | c.1947C>T p.A649= | Silent (SNP) | VAF 14/166 reads (8%) | catalogued as rs552568826, COSV54013730; called by muse, mutect2
- PCK1 | c.525G>A p.R175= | Silent (SNP) | VAF 17/152 reads (11%) | catalogued as rs750079773, COSV60130476; called by muse, mutect2, varscan2
- PLA2G3 | c.240C>T p.T80= | Silent (SNP) | VAF 14/101 reads (14%) | catalogued as rs148262601; called by muse, mutect2, varscan2
- PLEKHA6 | c.250C>T p.L84= | Silent (SNP) | VAF 31/191 reads (16%) | catalogued as COSV55339230; called by muse, mutect2, varscan2
- PLXNA4 | c.300C>T p.I100= | Silent (SNP) | VAF 22/114 reads (19%) | catalogued as rs184417672; called by muse, mutect2, varscan2
- PLXNB3 | c.2400G>A p.A800= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as rs782510404, COSV62801188; called by muse, mutect2, varscan2
- PPP2R3B | c.471C>T p.H157= | Silent (SNP) | VAF 10/111 reads (9%) | catalogued as rs760291163, COSV66814270; called by muse, mutect2
- PPRC1 | c.4963T>C p.L1655= | Silent (SNP) | VAF 24/115 reads (21%) | catalogued as COSV53387882; called by muse, mutect2, varscan2
- PTMA | c.69T>C p.V23= | Silent (SNP) | VAF 7/83 reads (8%) | catalogued as COSV58187949; called by muse, mutect2
- PWWP3B | c.1380G>A p.E460= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV61801400; called by muse, mutect2, varscan2
- SCN3A | c.4188G>A p.V1396= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as COSV51806656, COSV99328227; called by muse, mutect2, varscan2
- SEC24C | c.3090G>A p.K1030= | Silent (SNP) | VAF 19/115 reads (17%) | catalogued as COSV59544427; called by muse, mutect2, varscan2
- SEMA4D | c.1179C>T p.F393= | Silent (SNP) | VAF 13/104 reads (13%) | catalogued as rs765338663, COSV59393775; called by muse, mutect2, varscan2
- SEMA5B | c.2052C>T p.F684= | Silent (SNP) | VAF 35/179 reads (20%) | catalogued as rs1438591971, COSV52106279; called by muse, mutect2, varscan2
- SERPINA3 | c.552G>A p.V184= | Silent (SNP) | VAF 15/121 reads (12%) | catalogued as rs758221177, COSV67586951; called by muse, mutect2, varscan2
- SFRP4 | c.639G>A p.E213= | Silent (SNP) | VAF 7/70 reads (10%) | catalogued as rs890392766, COSV71412566; called by muse, mutect2
- SGK1 | c.1068C>T p.S356= | Silent (SNP) | VAF 6/75 reads (8%) | catalogued as COSV52814115; called by muse, mutect2
- SLC6A11 | c.369G>A p.R123= | Silent (SNP) | VAF 17/114 reads (15%) | catalogued as rs745791264, COSV54397931; called by muse, mutect2, varscan2
- SLCO5A1 | c.2241C>T p.F747= | Silent (SNP) | VAF 11/95 reads (12%) | catalogued as rs1294938615, COSV52655710; called by muse, mutect2, varscan2
- SP140 | c.657T>G p.G219= | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as COSV59454077; called by mutect2, varscan2
- SPACA1 | c.441C>T p.F147= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as COSV52760885; called by muse, mutect2, varscan2
- SPHKAP | c.507C>T p.N169= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as rs572513712, COSV60891446; called by muse, mutect2, varscan2
- STAB2 | c.1473C>T p.I491= | Silent (SNP) | VAF 6/70 reads (9%) | catalogued as COSV66345424; called by muse, mutect2
- TCL1A | c.189C>T p.T63= | Silent (SNP) | VAF 20/135 reads (15%) | catalogued as COSV68086111; called by muse, mutect2, varscan2
- TENM3 | c.6588C>T p.F2196= | Silent (SNP) | VAF 19/84 reads (23%) | catalogued as rs772072490, COSV69316753; called by muse, mutect2, varscan2
- TMEM63A | c.750C>T p.D250= | Silent (SNP) | VAF 10/90 reads (11%) | catalogued as rs200715020, COSV64762319; called by muse, mutect2
- TMPRSS9 | c.858G>A p.T286= (on ENST00000648592; = p.T252= on NM_182973.2) | Silent (SNP) | VAF 21/83 reads (25%) | catalogued as rs759889003, COSV60225679; called by muse, mutect2, varscan2
- TNS3 | c.2862C>T p.P954= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as rs1386316682, COSV60797282; called by muse, mutect2, varscan2
- TRANK1 | c.7362G>A p.K2454= | Silent (SNP) | VAF 13/83 reads (16%) | catalogued as COSV57161660; called by muse, mutect2, varscan2
- TRIM50 | c.855C>T p.L285= | Silent (SNP) | VAF 13/86 reads (15%) | catalogued as COSV60795574; called by muse, mutect2, varscan2
- TRIO | c.7479C>T p.P2493= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as rs777155345, COSV59992179; called by muse, varscan2
- UBXN7 | c.603C>T p.F201= | Silent (SNP) | VAF 20/175 reads (11%) | catalogued as COSV56357265; called by muse, mutect2, varscan2
- UNC119 | c.591C>T p.P197= | Silent (SNP) | VAF 15/102 reads (15%) | catalogued as COSV56380036, COSV99971643; called by muse, mutect2, varscan2
- USP6 | c.2043C>T p.F681= | Silent (SNP) | VAF 11/72 reads (15%) | catalogued as COSV100003513; called by muse, mutect2, varscan2
- WDFY3 | c.6486G>A p.L2162= | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as rs140312391; called by muse, mutect2, varscan2
- XDH | c.2460C>A p.T820= | Silent (SNP) | VAF 38/235 reads (16%) | catalogued as COSV65150812; called by muse, mutect2, varscan2
- ZNF750 | c.1107C>T p.D369= | Silent (SNP) | VAF 22/257 reads (9%) | catalogued as COSV53962387; called by muse, mutect2
- EPHA8 | c.1315+87G>A | Intron (SNP) | VAF 10/94 reads (11%) | catalogued as COSV99384493; called by muse, mutect2
- SSPOP | n.6660C>T | RNA (SNP) | VAF 8/96 reads (8%) | catalogued as COSV50487140; called by muse, mutect2
- TMEM105 | n.628G>A | RNA (SNP) | VAF 31/144 reads (22%) | catalogued as COSV59655788; called by muse, mutect2, varscan2
- TTN | c.10360+1401C>T | Intron (SNP) | VAF 5/26 reads (19%) | catalogued as COSV100601535, COSV59902402; called by muse, mutect2, varscan2
